Somatic mutation profile of tumor specimen MMRF_2194_1_BM_CD138pos (aliquot MMRF_2194_1_BM_CD138pos_T1_KHS5U_L08794) from MMRF case MMRF_2194, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.5 years (27,574 days).
Specimen MMRF_2194_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f52608f2-7723-4914-aa76-bbb3c9695cdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2194_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2194_1_PB_WBC_C3_KHS5U_L08801; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e13e0b3-9a17-4143-b5b9-02cf26e26708

The open-access MAF lists 179 somatic variants for this specimen: 75 protein-altering or splice-affecting, 21 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, 3'UTR 38, Intron 23, Silent 21, 5'UTR 10, Nonsense Mutation 7, 5'Flank 5, RNA 4, 3'Flank 3, Splice Region 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- TP53 | c.783-1G>A p.X261_splice | Splice Site (SNP) | VAF 24/34 reads (71%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2029C>A p.L677I (on ENST00000272895 / NM_173076.3; = p.L359I on NM_015657.3) | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as rs1441753767; called by muse, mutect2
- ABCA12 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV55960224; called by muse, mutect2, varscan2
- AC068580.4 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.155); catalogued as rs904430565; called by muse, mutect2
- ADAM12 | c.926T>A p.V309D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64116378; called by muse, mutect2, varscan2
- CCKAR | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as COSV55160045, COSV55164469; called by muse, mutect2, varscan2
- CCNA2 | c.946A>C p.T316P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV99697243; called by muse, mutect2, varscan2
- DENND4C | c.4549C>G p.H1517D (on ENST00000434457 / NM_001330640.2; = p.H1468D on NM_017925.7) | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.586); catalogued as rs779176610; called by muse, mutect2, varscan2
- DNAJB9 | c.302G>T p.R101I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as rs1219797448; called by muse, mutect2, varscan2
- DOC2A | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV58752540; called by muse, mutect2, varscan2
- EEF1G | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 68/165 reads (41%) | catalogued as rs1418015966, COSV100240422; called by muse, mutect2, varscan2
- G6PC3 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1313517305; called by muse, mutect2, varscan2
- GABRA1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.257); catalogued as COSV50115453, COSV99196262; called by muse, mutect2, varscan2
- HDLBP | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV60500408; called by muse, mutect2, varscan2
- IGLV3-1 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs563308501; called by muse, mutect2, varscan2
- IL4R | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 95/299 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs780006435, COSV50189985; called by muse, mutect2, varscan2
- KALRN | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53783272; called by muse, mutect2, varscan2
- LIMA1 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as COSV57965146; called by muse, mutect2, varscan2
- MED1 | c.3464C>T p.S1155F | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as rs991207806; called by muse, mutect2, varscan2
- NDST4 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV52113044; called by muse, mutect2, varscan2
- PCDHB16 | c.1377C>A p.F459L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV53358498; called by muse, mutect2
- SLC26A9 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV100535911, COSV61602794; called by muse, mutect2
- SMPDL3A | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs749498675; called by muse, varscan2
- TMEM132C | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs975014093; called by muse, mutect2
- TMEM225 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.32); catalogued as COSV66693869; called by muse, mutect2, varscan2
- ZKSCAN1 | c.851C>G p.S284W | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752416389; called by muse, mutect2, varscan2
- ZNF431 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1414858307, COSV60673126; called by muse, mutect2, varscan2
- ADGRB1 | c.2432T>C p.V811A | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKFN1 | c.2215C>A p.P739T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); called by muse, mutect2
- ANKRD34C | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2
- ARHGAP29 | c.3163G>A p.G1055R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ARHGAP5 | c.2797C>G p.L933V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ATRIP | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- BAG5 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CCDC168 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CCR8 | c.433A>T p.R145W | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42EP3 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CIITA | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- COL25A1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- EME1 | c.1688A>T p.H563L | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EZH1 | c.853G>T p.V285L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FBH1 | c.2323-3C>T | Splice Region (SNP) | VAF 17/228 reads (7%) | called by muse, mutect2
- FMNL1 | c.2734C>G p.L912V | Missense Mutation (SNP) | VAF 117/286 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IGHV2-70D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- INHBC | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MCL1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, varscan2
- MDN1 | c.15592G>T p.E5198* | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- MORC1 | c.1788A>T p.K596N | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MRGPRX4 | c.564T>A p.C188* | Nonsense Mutation (SNP) | VAF 56/128 reads (44%) | called by mutect2, varscan2
- MYO1E | c.2034C>G p.I678M | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NKAIN2 | c.10T>A p.C4S | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- NMNAT2 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- PCDHGA8 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PER3 | c.2889G>C p.E963D | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.121); called by muse, varscan2
- PIK3R2 | c.381_395del p.L128_V132del | In Frame Del (DEL) | VAF 56/180 reads (31%) | called by mutect2, pindel, varscan2
- PLEKHA5 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- PNPLA5 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR1B | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- RREB1 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SKOR2 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SNX27 | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SORBS2 | c.2022C>G p.H674Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRRM2 | c.4473G>C p.Q1491H | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SYNE2 | c.10344G>C p.E3448D | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCIM | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TK1 | c.335T>C p.M112T | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TNRC6C | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- TRAPPC10 | c.613A>C p.M205L | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TREML2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TUBGCP5 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE4B | c.3563C>G p.S1188* (on ENST00000343090 / NM_001105562.3; = p.S1059* on NM_006048.5) | Nonsense Mutation (SNP) | VAF 54/150 reads (36%) | called by muse, mutect2, varscan2
- UGDH | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); called by muse, mutect2
- XPO6 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- ZNF570 | c.666C>A p.D222E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMDHD1 | c.1146G>C p.S382= | Silent (SNP) | VAF 56/120 reads (47%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.2829C>T p.T943= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs748386653; called by muse, mutect2, varscan2
- ATN1 | c.3322C>T p.L1108= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV57547471; called by muse, mutect2, varscan2
- ATRIP | c.1026C>T p.G342= | Silent (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- BPNT2 | c.1005C>G p.L335= | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- CMSS1 | c.444G>A p.K148= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- COG7 | c.1273C>T p.L425= | Silent (SNP) | VAF 91/158 reads (58%) | called by muse, mutect2, varscan2
- DSCAML1 | c.2892C>T p.N964= (on ENST00000321322; = p.N904= on NM_020693.4) | Silent (SNP) | VAF 62/126 reads (49%) | catalogued as COSV58402945; called by muse, mutect2, varscan2
- FAT4 | c.11688T>A p.G3896= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2
- FBXL5 | c.30C>G p.V10= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs200927708; called by muse, mutect2, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as rs1233195687; called by muse, varscan2
- MCL1 | c.528G>C p.R176= | Silent (SNP) | VAF 98/230 reads (43%) | called by muse, varscan2
- NFIC | c.279G>C p.V93= | Silent (SNP) | VAF 17/214 reads (8%) | catalogued as COSV59411186; called by muse, mutect2
- NOC3L | c.78C>T p.N26= | Silent (SNP) | VAF 49/123 reads (40%) | called by muse, mutect2, varscan2
- PMM1 | c.234C>T p.A78= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs376284083; called by muse, mutect2, varscan2
- PRSS36 | c.1434C>G p.R478= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- QRICH2 | c.747C>T p.L249= | Silent (SNP) | VAF 33/141 reads (23%) | called by muse, mutect2, varscan2
- SLC9A5 | c.1371G>A p.K457= | Silent (SNP) | VAF 74/102 reads (73%) | called by muse, mutect2, varscan2
- THAP5 | c.300C>T p.S100= (on ENST00000415914 / NM_001130475.3; = p.S58= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/232 reads (28%) | catalogued as rs776756092; called by mutect2, varscan2
- ZNFX1 | c.3138C>T p.A1046= | Silent (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- ZWINT | c.657G>T p.L219= | Silent (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- AC119673.2 | n.268C>A | RNA (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- AC136628.2 | n.936C>G | RNA (SNP) | VAF 15/62 reads (24%) | catalogued as rs1458286355; called by muse, mutect2, varscan2
- ADGRL2 | c.-248+56982G>T | Intron (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- ANO1 | c.109-2216C>T | Intron (SNP) | VAF 86/207 reads (42%) | called by muse, mutect2
- ANO1 | c.*10C>T | 3'UTR (SNP) | VAF 7/13 reads (54%) | catalogued as rs371273815; called by muse, mutect2, varscan2
- APOLD1 | c.-44C>G | 5'UTR (SNP) | VAF 57/172 reads (33%) | called by muse, mutect2, varscan2
- ARX | c.*161C>T | 3'UTR (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100984042; called by muse, mutect2, varscan2
- ASH1L | c.5828+4815G>T | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- ATXN1 | c.*3759C>G | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- BEND4 | c.*6268A>G | 3'UTR (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- CACNB2 | c.*884G>C | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- CADM1 | c.*1749C>T | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- CAMKK2 | c.1596+482A>C | Intron (SNP) | VAF 97/221 reads (44%) | called by muse, varscan2
- CARMIL2 | c.1591+34C>T | Intron (SNP) | VAF 80/143 reads (56%) | called by muse, mutect2, varscan2
- CD81 | c.67-4236G>T | Intron (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2
- CKAP2L | c.*664G>C | 3'UTR (SNP) | VAF 4/93 reads (4%) | called by muse, mutect2
- CNPY4 | c.*515G>C | 3'UTR (SNP) | VAF 30/65 reads (46%) | catalogued as rs888236230; called by muse, mutect2, varscan2
- CNTNAP3B | c.1072-2059G>A | Intron (SNP) | VAF 34/185 reads (18%) | called by muse, mutect2, varscan2
- COA1 | c.-38-958A>G | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- COMT | c.615+424C>T | Intron (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- CXCL11 | c.*1032G>A | 3'UTR (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- DHX36 | c.*2541G>A | 3'UTR (SNP) | VAF 5/108 reads (5%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.*94C>A | 3'UTR (SNP) | VAF 19/168 reads (11%) | called by muse, mutect2, varscan2
- EGFR | c.*4002G>A | 3'UTR (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- EYA4 | chr6:133531711 C>T | 3'Flank (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- FANCM | c.*821C>T | 3'UTR (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2, varscan2
- FBLN1 | c.1698-9615G>A | Intron (SNP) | VAF 30/69 reads (43%) | catalogued as COSV53046799; called by muse, mutect2, varscan2
- GDE1 | c.*691C>T | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, varscan2
- GGH | c.835+86C>G | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- GRIA4 | c.247+589A>G | Intron (SNP) | VAF 33/46 reads (72%) | called by muse, mutect2, varscan2
- HTR3B | c.-100G>A | 5'UTR (SNP) | VAF 39/113 reads (35%) | called by mutect2, varscan2
- IGSF9B | chr11:133956906 C>T | 5'Flank (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- IL10RB | c.-28G>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | catalogued as rs959114759; called by muse, mutect2, varscan2
- KAT7 | c.-153C>T | 5'UTR (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- KCNJ4 | c.-30C>G | 5'UTR (SNP) | VAF 44/90 reads (49%) | catalogued as COSV100341554; called by muse, mutect2, varscan2
- KIF2A | chr5:62386407 A>G | 3'Flank (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- LGI1 | c.432-50T>C | Intron (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- LIN9 | c.*1174del | 3'UTR (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- LMAN1 | c.*2490G>C | 3'UTR (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- MCF2L | chr13:113099082 G>A | 3'Flank (SNP) | VAF 20/72 reads (28%) | catalogued as rs1026537027; called by muse, mutect2, varscan2
- MCTS1 | c.11+143C>G | Intron (SNP) | VAF 90/109 reads (83%) | called by muse, mutect2, varscan2
- MGAT3 | c.*2503C>G | 3'UTR (SNP) | VAF 32/79 reads (41%) | catalogued as rs939839691; called by muse, mutect2, varscan2
- MIR31 | n.7G>A | RNA (SNP) | VAF 7/65 reads (11%) | called by mutect2, varscan2
- MMP16 | c.-12G>A | 5'UTR (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- MYCBPAP | c.-9G>A | 5'UTR (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- NFYA | c.*1820A>T | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- NPTXR | c.*2047T>C | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- NR4A1 | c.1158+122G>C | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2
- OGDH | c.*225T>C | 3'UTR (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- PISD | c.*182G>A | 3'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*4191G>A | 3'UTR (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- PNCK | c.-2-248C>T | Intron (SNP) | VAF 66/74 reads (89%) | called by muse, varscan2
- PPP1R1B | c.*606G>C | 3'UTR (SNP) | VAF 8/148 reads (5%) | catalogued as COSV99566160; called by muse, mutect2
- PPP1R37 | chr19:45093112 A>G | 5'Flank (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+3818G>A | Intron (SNP) | VAF 35/102 reads (34%) | catalogued as rs906630982; called by muse, mutect2, varscan2
- RABGGTB | chr1:75786183 G>A | 5'Flank (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- RN7SL176P | chr12:100158921 G>A | 5'Flank (SNP) | VAF 38/100 reads (38%) | catalogued as rs759587404; called by muse, mutect2, varscan2
- RPL35 | c.3+42C>G | Intron (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- SCAF11 | chr12:45992025 G>T | 5'Flank (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- SCN1A | c.*1913C>G | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by mutect2, varscan2
- SDF2L1 | c.384+28G>C | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- SFRP2 | c.*516C>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs1560809333; called by muse, mutect2, varscan2
- SHANK1 | c.1222+120G>A | Intron (SNP) | VAF 42/77 reads (55%) | called by muse, mutect2, varscan2
- SHROOM3 | c.*2311T>C | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- SLC25A36 | c.386-148T>C | Intron (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- SLC26A2 | c.*3427_*3447del | 3'UTR (DEL) | VAF 25/60 reads (42%) | called by mutect2, pindel, varscan2
- SLC2A13 | c.*1015dup | 3'UTR (INS) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- SLC35E2B | c.-101C>G | 5'UTR (SNP) | VAF 6/117 reads (5%) | called by muse, mutect2
- SLC7A7 | c.*130T>G | 3'UTR (SNP) | VAF 66/188 reads (35%) | called by muse, varscan2
- SLFN13 | c.*2401G>A | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- SNX30 | c.*4485A>T | 3'UTR (SNP) | VAF 46/107 reads (43%) | catalogued as rs1299197789; called by muse, mutect2, varscan2
- SRRM4 | c.-290G>C | 5'UTR (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- TCIM | c.-42C>A | 5'UTR (SNP) | VAF 72/124 reads (58%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+1276T>C | Intron (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- TMEM26 | c.*3335A>G | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, varscan2
- TOM1 | c.899+914G>A | Intron (SNP) | VAF 8/98 reads (8%) | catalogued as rs1322964724; called by muse, mutect2
- TRIQK | c.*849C>G | 3'UTR (SNP) | VAF 22/71 reads (31%) | catalogued as COSV66649519; called by muse, mutect2, varscan2
- TTL | c.*354del | 3'UTR (DEL) | VAF 34/99 reads (34%) | called by mutect2, pindel, varscan2
- USP2-AS1 | n.1278T>C | RNA (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- USP46 | c.*2596T>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as COSV71513100; called by muse, mutect2
- ZBTB21 | c.*3463G>A | 3'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- ZNF532 | c.*1478G>A | 3'UTR (SNP) | VAF 92/319 reads (29%) | called by muse, mutect2, varscan2
- ZSCAN23 | c.*1619T>G | 3'UTR (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
